Somatic mutation profile of tumor specimen MMRF_2223_1_BM_CD138pos (aliquot MMRF_2223_1_BM_CD138pos_T1_KHS5U_L11014) from MMRF case MMRF_2223, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.1 years (29,974 days).
Specimen MMRF_2223_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6101a2c-ec82-4813-b0c6-219d117efaa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2223_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2223_1_PB_Whole_C2_KHS5U_L11015; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24e80e3f-c360-404d-894b-de8771eb011a

The open-access MAF lists 120 somatic variants for this specimen: 44 protein-altering or splice-affecting, 16 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 37, Silent 16, Intron 12, RNA 4, 3'Flank 3, Nonsense Mutation 3, 5'Flank 2, 5'UTR 2, In Frame Ins 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 15/93 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 21/151 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4331A>G p.Q1444R | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs754829821, COSV63244156; called by muse, mutect2, varscan2
- EXOC3L4 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs757105801, COSV66295448, COSV66295527; called by muse, mutect2, varscan2
- GEMIN6 | c.211A>G p.M71V | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs201716703; called by muse, mutect2
- HERC2 | c.11962G>A p.V3988M | Missense Mutation (SNP) | VAF 104/212 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs374245104, COSV99874428; called by muse, mutect2, varscan2
- IGLV3-1 | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs369545397; called by muse, varscan2
- IGLV3-1 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs143830449; called by muse, varscan2
- ITGB4 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1233389477; called by muse, mutect2, varscan2
- JARID2 | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs754929108; called by muse, mutect2, varscan2
- KCNA1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1253210703, COSV66836612; called by muse, mutect2, varscan2
- NEU4 | c.628C>A p.R210S (on ENST00000391969 / NM_001167602.3; = p.R222S on NM_080741.4) | Missense Mutation (SNP) | VAF 114/207 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs370002261, COSV57991448; called by muse, mutect2, varscan2
- NUP205 | c.4616T>G p.L1539* | Nonsense Mutation (SNP) | VAF 21/126 reads (17%) | catalogued as COSV53664448; called by muse, mutect2, varscan2
- ORAI1 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV57492495; called by muse, mutect2, varscan2
- PDCD11 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs549702407; called by muse, mutect2, varscan2
- RASGRF1 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769371347, COSV69180503; called by muse, mutect2
- TCF4 | c.1715G>T p.R572L | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM092438; called by muse, mutect2
- VCPIP1 | c.1634C>G p.S545C | Missense Mutation (SNP) | VAF 57/415 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as rs1019384396, COSV60047191; called by muse, mutect2, varscan2
- ANKRD45 | c.743G>C p.S248T | Missense Mutation (SNP) | VAF 162/353 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ARSK | c.1452_1454dup p.N484dup | In Frame Ins (INS) | VAF 28/72 reads (39%) | called by mutect2, varscan2
- ATAD5 | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 157/328 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CDH10 | c.107T>C p.I36T | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP68 | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.018); called by muse, mutect2
- DAAM2 | c.3014A>C p.Q1005P (on ENST00000274867 / NM_001201427.2; = p.Q1004P on NM_015345.3) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- DLX6 | c.848A>C p.H283P | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2AK3 | c.880A>C p.I294L | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GLIPR1L2 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HDAC9 | c.406+2dup p.X136_splice | Splice Site (INS) | VAF 8/86 reads (9%) | called by mutect2, pindel
- KPNB1 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- MDGA2 | c.943C>T p.L315F (on ENST00000399232 / NM_001113498.2; = p.L17F on NM_182830.4) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MPDZ | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 73/156 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OCSTAMP | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PHF21B | c.1498A>G p.T500A | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIGH | c.61T>G p.Y21D | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C2B | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PLXDC1 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PZP | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SCG5 | c.373del p.T125Qfs*7 (on ENST00000300175 / NM_001144757.2; = p.T125Qfs*6 on NM_003020.4) | Frame Shift Del (DEL) | VAF 9/94 reads (10%) | called by mutect2, pindel
- SMC5 | c.3010T>A p.L1004M | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPEF2 | c.5222C>T p.A1741V | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2
- TAOK1 | c.2453A>G p.K818R | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMPO | c.1093A>T p.R365* | Nonsense Mutation (SNP) | VAF 25/309 reads (8%) | called by muse, mutect2
- UBE2N | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- VCPIP1 | c.1316T>G p.F439C | Missense Mutation (SNP) | VAF 53/360 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- APOB | c.13539T>C p.F4513= | Silent (SNP) | VAF 62/284 reads (22%) | called by muse, mutect2, varscan2
- CAMK2B | c.1284C>T p.A428= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as rs373048588; called by muse, mutect2, varscan2
- CDON | c.2436T>C p.P812= | Silent (SNP) | VAF 25/161 reads (16%) | catalogued as rs1177799337; called by muse, mutect2, varscan2
- DNAH5 | c.8175T>C p.S2725= | Silent (SNP) | VAF 78/186 reads (42%) | called by muse, mutect2, varscan2
- FANCI | c.3657G>A p.K1219= (on ENST00000310775 / NM_001376911.1; = p.K1159= on NM_018193.3) | Silent (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2, varscan2
- FOSL1 | c.195C>T p.P65= | Silent (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- IGHJ5 | c.15C>T p.P5= | Silent (SNP) | VAF 24/26 reads (92%) | catalogued as rs782527450; called by muse, varscan2
- IGHV1OR15-9 | c.282C>G p.S94= | Silent (SNP) | VAF 43/267 reads (16%) | called by muse, mutect2, varscan2
- INA | c.1038G>A p.R346= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- OSMR | c.2826T>C p.C942= | Silent (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- SLC30A9 | c.1500T>A p.V500= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as rs1392460250, COSV52558997; called by muse, mutect2
- TMSB4X | c.69G>T p.T23= | Silent (SNP) | VAF 79/85 reads (93%) | catalogued as rs1468143765, COSV66081143; called by muse, mutect2, varscan2
- TMX3 | c.150G>A p.A50= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as rs552312818; called by muse, mutect2, varscan2
- UHRF1 | c.537G>A p.E179= (on ENST00000612630 / NM_001290050.1; = p.E192= on NM_013282.4) | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- UNC13A | c.3856C>T p.L1286= | Silent (SNP) | VAF 92/165 reads (56%) | catalogued as rs1178432956; called by muse, mutect2, varscan2
- ZNF17 | c.534T>C p.H178= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as rs1361573683; called by muse, mutect2
- AC015910.1 | chr17:39245721 T>G | 3'Flank (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2
- ACTR3B | c.*642A>G | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- ADAD2 | c.419-45G>A | Intron (SNP) | VAF 52/127 reads (41%) | catalogued as rs1209215688; called by muse, mutect2, varscan2
- ADAMTS19 | c.*797T>C | 3'UTR (SNP) | VAF 40/84 reads (48%) | called by muse, mutect2, varscan2
- ADRA2A | c.*389C>T | 3'UTR (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- AKT3 | c.*1604G>T | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- AP000679.1 | n.1185C>T | RNA (SNP) | VAF 37/90 reads (41%) | catalogued as rs996541630; called by muse, mutect2, varscan2
- ARFGAP1 | c.718-453T>G | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- BAG5 | c.*1462A>G | 3'UTR (SNP) | VAF 22/114 reads (19%) | called by muse, mutect2, varscan2
- BCCIP | c.850+1265C>T | Intron (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- BCL11B | c.*3866T>G | 3'UTR (SNP) | VAF 73/143 reads (51%) | called by muse, mutect2, varscan2
- C19orf44 | c.*1021A>G | 3'UTR (SNP) | VAF 4/61 reads (7%) | catalogued as rs1477046636; called by muse, mutect2
- C1D | c.*24A>G | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- CALCR | c.*1320T>C | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- CALM2 | c.-60T>G | 5'UTR (SNP) | VAF 34/273 reads (12%) | catalogued as rs1261871733; called by muse, mutect2, varscan2
- CALN1 | c.*6686A>C | 3'UTR (SNP) | VAF 67/130 reads (52%) | called by muse, mutect2, varscan2
- CAMK4 | c.*409C>T | 3'UTR (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- CBX6 | c.*2304G>A | 3'UTR (SNP) | VAF 126/275 reads (46%) | called by muse, mutect2, varscan2
- CIP2A | c.*1015G>A | 3'UTR (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- CKAP2 | c.*1146C>T | 3'UTR (SNP) | VAF 16/24 reads (67%) | catalogued as rs1261642989; called by mutect2, varscan2
- CTXN2 | c.*949G>T | 3'UTR (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- DNM1L | c.251-1339C>T | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- ERBB4 | c.*5010A>T | 3'UTR (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- FGL2 | c.*2421A>C | 3'UTR (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2, varscan2
- GDNF | c.*1531C>G | 3'UTR (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2, varscan2
- GTF3C3 | c.1218+16T>G | Intron (SNP) | VAF 64/403 reads (16%) | called by muse, mutect2, varscan2
- HOMER1 | c.*2328G>C | 3'UTR (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- IBA57 | c.*5937C>G | 3'UTR (SNP) | VAF 65/136 reads (48%) | called by muse, mutect2, varscan2
- IL1R1 | c.1303+50A>G | Intron (SNP) | VAF 46/95 reads (48%) | called by muse, mutect2, varscan2
- INKA2 | c.*211T>C | 3'UTR (SNP) | VAF 97/190 reads (51%) | called by muse, varscan2
- INPP4B | chr4:142025021 A>C | 3'Flank (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2, varscan2
- KCNT1 | c.618+19C>T | Intron (SNP) | VAF 70/378 reads (19%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+6721C>T | Intron (SNP) | VAF 27/190 reads (14%) | catalogued as rs1382537064, COSV55803233; called by muse, mutect2, varscan2
- KLHDC7A | c.*265G>T | 3'UTR (SNP) | VAF 105/197 reads (53%) | called by muse, mutect2, varscan2
- LGI2 | c.*3483C>T | 3'UTR (SNP) | VAF 24/486 reads (5%) | called by muse, mutect2
- LONRF2 | c.*5680G>A | 3'UTR (SNP) | VAF 38/181 reads (21%) | catalogued as rs1163616951; called by muse, mutect2, varscan2
- LTB | c.163-127G>C | Intron (SNP) | VAF 187/391 reads (48%) | called by muse, mutect2, varscan2
- LTB | c.162+84C>T | Intron (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- MAST4 | c.*274A>G | 3'UTR (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- MIR548G | n.2G>A | RNA (SNP) | VAF 9/216 reads (4%) | called by muse, mutect2
- MPV17 | chr2:27324557 G>T | 5'Flank (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- MSL3P1 | n.253G>A | RNA (SNP) | VAF 86/172 reads (50%) | called by muse, mutect2, varscan2
- OSBPL3 | c.*1949T>A | 3'UTR (SNP) | VAF 45/91 reads (49%) | called by muse, mutect2, varscan2
- PLXND1 | c.*748G>A | 3'UTR (SNP) | VAF 10/267 reads (4%) | called by muse, mutect2
- RXFP3 | c.*419G>A | 3'UTR (SNP) | VAF 18/198 reads (9%) | catalogued as rs888153340; called by muse, mutect2
- SCAND1 | c.-150C>T | 5'UTR (SNP) | VAF 18/238 reads (8%) | catalogued as rs545354984; called by muse, mutect2
- SEC62 | chr3:169966705 C>T | 5'Flank (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2
- SLC22A5 | c.*785T>C | 3'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- SLC26A7 | c.*10G>T | 3'UTR (SNP) | VAF 19/375 reads (5%) | called by muse, mutect2
- SLC5A3 | c.*5541G>A | 3'UTR (SNP) | VAF 4/60 reads (7%) | catalogued as rs1422557629; called by muse, mutect2
- SNRPG | c.32+364T>G | Intron (SNP) | VAF 84/519 reads (16%) | called by muse, mutect2, varscan2
- SOX9 | c.*1136G>A | 3'UTR (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- SYNPO2 | c.*5277T>G | 3'UTR (SNP) | VAF 16/511 reads (3%) | called by muse, mutect2
- TRIM58 | c.*645T>A | 3'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- UBE2D3 | chr4:102795213 A>G | 3'Flank (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- VWA2 | c.2122+93C>T | Intron (SNP) | VAF 174/395 reads (44%) | catalogued as rs767275086; called by muse, mutect2, varscan2
- XIRP2 | c.*506A>C | 3'UTR (SNP) | VAF 129/269 reads (48%) | called by muse, mutect2, varscan2
- XPNPEP3 | c.*5916A>T | 3'UTR (SNP) | VAF 26/58 reads (45%) | catalogued as rs1234908066; called by muse, varscan2
- YLPM1 | c.*41T>C | 3'UTR (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2
- ZNF971P | n.385G>A | RNA (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
